Gene-level copy-number profile of tumor specimen C3N-06052-02 from CPTAC case C3N-06052, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 70.4 years (25,708 days).
Specimen C3N-06052-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78621b47-fd39-4764-8af0-e01c4a064cca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-06052-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/dbc58d7c-9181-4524-af3c-2857ba4192f4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 212; copy number 1: 8,420; copy number 2: 46,284; copy number 3: 57; copy number 4: 1,964; copy number 5: 1,459.

Homozygous deletions (total copy number 0; autosomes only): 212 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,524,185, 5 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr8:7,601,004–7,868,867, 18 genes: AC134684.1, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A.
- chr9:20,331,446–23,438,700, 70 genes (broad region; genes not listed).
- chr14:21,841,240–22,552,156, 119 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,459 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–114,318,911, 999 genes, copy number 5 (broad region; genes not listed).
- chr8:116,642,130–130,017,129, 198 genes, copy number 5 (broad region; genes not listed).
- chr8:133,237,175–145,066,685, 258 genes, copy number 5 (broad region; genes not listed).
- chr21:46,598,604–46,691,226, 4 genes, copy number 5: S100B, PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 8,420. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
